Surgical pathology report (de-identified scan), TCGA case TCGA-DU-A7TD, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-A7TD-01A (Primary Tumor).

[page 1 of 4]
Surgical Pathology Report

Patient Name: Phone #:

Med. Rec. #: Client: ' "

DOB: (Age:) Location:

Gender: M Acctnt: Reported:

Physician(s):

Phy Location:

Clinical History

-year-old man experienced falls ago, and was emergently decompressed of a large right temporal lobe tumor that extended to the frontal lobe and insula, with herniation.

Operative Diagnoses

Right temporal brain mass.

Operation / Specimen

A: Brain, excision biopsy

Pathologic Diagnosis

Brain, right temporal, excision: Mixed oligoastrocytoma, anaplastic (WHO grade III).

See Microscopy Description and Comment.

Comment

The sections contain large portions of brain extensively infiltrated and effaced by a very cellular glial neoplastic proliferation. The neoplastic cells have a mixed oligo astrocytic phenotype, there is focally brisk mitotic activity, and the MIB-1 proliferation index is about 75% in the more active areas. There is also focal endothelial hyperplasia and some microvascular proliferation. There are focal areas of necrosis and hemorrhage with some pigment, most likely associated with previous surgical procedure.

The findings are interpreted as those of an anaplastic oligoastrocytoma.

Electronically Signed Out

Consultant:

Pathologist

, Senior Staff Pathologist

., Senior Staff

Procedures/Addenda

PCR for EGFR variant III mutation

Date Ordered:

Date Reported:

Interpretation

Surgical Pathology

Page 2 of 4

NEGATIVE - No evidence of EGFRvIII mutation is detected

Results-Comments

TEST DESCRIPTION: Testing performed on RNA extracted from paraffin tissue block (A1)

H and E slide was examined and no microdissection was needed.

The epidermal growth factor receptor (EGFR) is an attractive molecular target in glioblastoma because it is amplified, overexpressed, and/or mutated in up to 40% to 50% of patients. Epidermal growth factor receptor variant III

(EGFRvIII) is an oncogenic, constitutively active mutant form of EGFR that is commonly expressed in glioblastoma.

ICD O-3

Oligoastrocytoma, grade III

CHE

9382/3

Site: Brain, supratentorial

NOS C71.0

with

Brain, temporal lobe

C71.2

4/22/14

[page 2 of 4]
Cell culture and in vivo models of glioblastoma have demonstrated EGFRvIII as defining prognostically distinct subgroups of glioblastomas. Additionally, the presence of EGFRvIII has been shown to sensitize tumors to EGFR tyrosine kinase inhibitors when the tumor suppressor protein PTEN is intact. RNA is extracted from formalin fixed, paraffin embedded tissue samples and reverse transcribed to cDNA. The cDNA is then amplified using standard PCR technique for DNA templates. PCR products are detected by gel electrophoresis. The limit of detection of this assay has been determined to be approximately 5 mutant cells in 100 normal cells.
FDA Comment: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the as required by CLIA '88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.
Electronically Signed Out

Senior Staff Pathologist

Loss of Heterozygosity 1p, 19q Assay (LOH)

Date Ordered:

Date Reported:

Interpretation

NEGATIVE: Allelic loss on chromosome arm 1p and chromosome arm 19q is NOT detected.

Informative loci are: D1S1612, D1S496, D19S219, D19S412, and PLA2G4C

Results-Comments

Testing performed on DNA extracted from tumor paraffin block (A1). DNA extracted from a corresponding blood specimen was used as a normal reference control.

H and E slide was examined and no microdissection was needed.

TEST DESCRIPTION: Allelic loss is assessed by PCR assay in Normal DNA (baseline)/ Tumor DNA pairs using 3

markers at both 1p and 19q. The 3 markers on 1p are D1S548, D1S1592, and D1S552 (with D1S468, D1S1612, and D1S496 as backup markers) and the 3 markers on 19q are D19S219, D19S412, and PLA2G4C (with D19S606 and

D19S1182 as backup). All markers are microsatellites (2 or 4 nt repeats) except PLA2G4C which is a minisatellite (26

nt repeat) polymorphism. The markers were selected based on heterozygosity score, amplicon size, and ease of

interpretation. The backup markers are used if the first line markers at that chromosome arm are uninformative or

otherwise ambiguous in their interpretation. LOH at all informative loci on each chromosomal arm represents the

typical finding in oligodendrogliomas with 1p and 19q deletion.

Surgical Pathology

Page 3 of 4

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test

was developed and its performance characteristics determined by the as required

by CLIA '88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug

[page 3 of 4]
Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

TECHNICAL SENSITIVITY: The presence of >15% non-neoplastic cells in the sample may preclude the detection of allelic loss.

Electronically Signed Out

, Senior Staff Pathologist

MGMT Promoter Methylation

Date Ordered: **Date Reported:**

Interpretation

NEGATIVE: No evidence of methylated MGMT promoter is detected.

Results-Comments

Testing performed on DNA extracted from tumor paraffin block -A1

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit

from therapy with alkylating agents. Assessment of MGMT promoter methylation status involves bisulfite treatment of

DNA followed by real-time PCR amplification of methylated and unmethylated DNA sequences. The

analytic sensitivity of this assay was determined by serial dilution of methylated positive control DNA into unmethylated DNA, and was assessed to be 1% of methylated DNA in the background of unmethylated DNA. Factors

such as the presence of >50% non-neoplastic cells in the sample, or extensive tissue necrosis, may preclude the

detection of methylated MGMT promoter sequences.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test

was developed and its performance characteristics determined by the as required

by CLIA '88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are

provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

Electronically Signed Out

M.D., Senior Staff Pathologist

Addendum

Date Ordered: **Date Reported:**

Addendum Diagnosis

Review of the slides confirms the diagnosis of a high-grade mixed oligodendroglial and astrocytic glioma.

A regional

area of increased cellular atypia and cellular density associated with focal microvascular proliferation is noted. Focal

necrosis is also present. Considering these features, the differential diagnosis includes a high-grade oligoastrocytoma

in transition to glioblastoma with oligodendroglial component, WHO grade IV. Clinical correlation is recommended.

Addendum Comment

This addendum is issued for the purpose of pathology review requested by the clinical oncology team for treatment

protocol considerations.

[page 4 of 4]
Surgical Pathology

Page 4 of 4

Electronically Signed Out

Senior Staff Pathologist

Gross Description

A.

Brain, excision biopsy:

CONTAINER LABEL: brain tumor.

FIXATIVE: Formalin. NO. PIECES: many red to gray tan fragments. SIZE/VOL: 5 x 4.5 x 2.0 cm; 15.55 grams

CASSETTES: 1-3,

Microscopic Description

IMMUNOHISTOCHEMISTRY: The GFAP demonstrates an overall sparse gliofibrillary back ground. The CD34

depicts a monotonous capillary-type microvascular network, with a few areas that have endothelial hyperplasia, and a

couple of areas with few vessels with microvascular cellular proliferation. Many cells weakly over express the p53

protein, and only a small minority strongly over expresses the protein. With the MIB-1 there is very high proliferation

index that reaches 75% in the more active areas.

ICD-9(s): 191.2 191.2

Billing Fee Code(s): A:

EGFRvIII:

LOH 1p19q:

MGMT:

Histo Data

Part A: Brain, excision biopsy

Taken: Received:

Stain/cnt Block Ordered Comment

CD34-DA x 1 1

EGFR-curls x 1 1

mGFAP-DA x 1 1

mGFAP-DA x 1 1

H&E x 1 1

LOH-curls x 1 1

MGMT-curls x 1 1

MIB1-DA x 1 1

P53DO7 x 1 1

H&E x 1 2

H&E x 1 3

Reviewer Initials	Date Re-reviewed	9/13/13

Source: NCI Genomic Data Commons file 45c8fd3a-ff10-41fb-802d-8d66630075d9 (TCGA-DU-A7TD.0DDAB8E8-54DA-495A-9A4B-9D9A3CFE5DB7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).